Somatic mutation profile of tumor specimen MP2PRT-PAUKUS-TMP1-A (aliquot MP2PRT-PAUKUS-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUKUS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,050 days).
Specimen MP2PRT-PAUKUS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dd6645c-f5f5-4263-bf50-363fe920b73b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKUS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKUS-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91dcd3d6-b12a-469c-a023-c3eca3d57229

The open-access MAF lists 81 somatic variants for this specimen: 54 protein-altering or splice-affecting, 20 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 20, Nonsense Mutation 13, Intron 4, 3'Flank 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.7666G>A p.E2556K | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV57225036; called by muse, mutect2, varscan2
- ANKRD6 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.668); catalogued as rs1466073879; called by muse, mutect2
- ASCL1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 53/581 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99902074; called by muse, mutect2
- CACNA1B | c.6238G>T p.A2080S | Missense Mutation (SNP) | VAF 147/330 reads (45%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.526); catalogued as COSV53152134; called by muse, varscan2
- CAMK2B | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.981); catalogued as rs370415166; called by muse, mutect2, varscan2
- CCDC168 | c.20608T>C p.S6870P | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59421574; called by muse, mutect2, varscan2
- DHX40 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52066091; called by muse, mutect2, varscan2
- DNLZ | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99395923; called by muse, mutect2
- GALNT13 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101222852; called by muse, mutect2
- INTS1 | c.2542C>G p.H848D | Missense Mutation (SNP) | VAF 16/329 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.062); catalogued as COSV67179885; called by muse, mutect2
- KDM5C | c.2150C>G p.S717* | Nonsense Mutation (SNP) | VAF 16/441 reads (4%) | catalogued as COSV64768979, COSV64769728; called by muse, mutect2
- LRIG1 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1486943349; called by muse, mutect2
- MKRN2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as COSV50103673; called by muse, mutect2
- RIMBP2 | c.2469C>T p.I823= | Splice Region (SNP) | VAF 23/300 reads (8%) | catalogued as rs1020189388; called by muse, mutect2
- SCN4B | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs778247172, COSV61251914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TESK1 | c.1196G>A p.S399N | Missense Mutation (SNP) | VAF 58/606 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV52410485; called by muse, mutect2
- TIGD7 | c.1262G>C p.R421T | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as rs139429241; called by muse, mutect2
- XPNPEP3 | c.1444C>G p.Q482E | Missense Mutation (SNP) | VAF 28/443 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64027704; called by muse, mutect2
- ZNF627 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV100741545; called by muse, mutect2
- ZNF627 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 41/413 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1030831047; called by muse, mutect2
- ABCC9 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); called by muse, mutect2
- ANKIB1 | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 30/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CABLES1 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- CAPN14 | c.1124G>A p.W375* | Nonsense Mutation (SNP) | VAF 17/246 reads (7%) | called by muse, mutect2
- CEP135 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- CLPTM1 | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 39/463 reads (8%) | called by muse, mutect2
- DLGAP3 | c.2354C>G p.S785* | Nonsense Mutation (SNP) | VAF 48/562 reads (9%) | called by muse, mutect2
- DNAAF5 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EFCAB5 | c.1655C>G p.S552* | Nonsense Mutation (SNP) | VAF 13/288 reads (5%) | called by muse, mutect2
- GNAT3 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 27/391 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2
- GPBAR1 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 44/601 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- HDAC5 | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- IL22RA2 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 26/305 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- JAML | c.682G>C p.D228H (on ENST00000356289 / NM_001098526.2; = p.D218H on NM_153206.3) | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- KDM5C | c.2822C>G p.S941* | Nonsense Mutation (SNP) | VAF 36/698 reads (5%) | called by muse, mutect2
- KLF6 | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 33/378 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.822); called by muse, mutect2
- LARP1 | c.1198C>G p.Q400E (on ENST00000518297 / NM_033551.3; = p.Q323E on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- MCOLN2 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MORC2 | c.1386C>G p.I462M (on ENST00000397641 / NM_001303256.3; = p.I400M on NM_014941.3) | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.278); called by muse, mutect2
- MYO1E | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 19/396 reads (5%) | called by muse, mutect2
- PLCB2 | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- PSTPIP2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 123/335 reads (37%) | called by muse, mutect2, varscan2
- PTPN13 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SASH1 | c.3394G>C p.E1132Q | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SCUBE1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 37/436 reads (8%) | called by muse, mutect2
- SCYGR6 | c.171T>A p.C57* | Nonsense Mutation (SNP) | VAF 250/639 reads (39%) | called by muse, mutect2, varscan2
- SELENOV | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 74/836 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.046); called by muse, mutect2
- SETD2 | c.2914G>T p.E972* | Nonsense Mutation (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- SETD2 | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SMYD4 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 24/351 reads (7%) | called by muse, mutect2
- TRPM5 | c.2032G>C p.E678Q | Missense Mutation (SNP) | VAF 35/398 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.209); called by muse, mutect2
- XDH | c.2906G>C p.W969S | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZCCHC2 | c.2656G>C p.E886Q | Missense Mutation (SNP) | VAF 36/437 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- ZZEF1 | c.6451G>C p.E2151Q | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); called by muse, mutect2
- CEP295 | c.420G>T p.L140= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- DGKQ | c.1131C>T p.P377= | Silent (SNP) | VAF 54/493 reads (11%) | catalogued as rs757376107; called by muse, mutect2, varscan2
- DRAXIN | c.66G>C p.L22= | Silent (SNP) | VAF 38/604 reads (6%) | called by muse, mutect2
- GALR3 | c.795C>T p.F265= | Silent (SNP) | VAF 60/671 reads (9%) | called by muse, mutect2
- GPR12 | c.723G>A p.S241= | Silent (SNP) | VAF 105/393 reads (27%) | catalogued as rs770835683, COSV67344258; called by muse, mutect2, varscan2
- IL18BP | c.516G>A p.L172= | Silent (SNP) | VAF 16/311 reads (5%) | catalogued as COSV52620198; called by muse, mutect2
- LINC00514 | c.1101G>A p.L367= | Silent (SNP) | VAF 35/353 reads (10%) | called by muse, mutect2, varscan2
- LRP1B | c.12183G>A p.L4061= | Silent (SNP) | VAF 51/206 reads (25%) | catalogued as rs772583073, COSV67249150; called by muse, mutect2, varscan2
- OR14I1 | c.399G>T p.V133= | Silent (SNP) | VAF 32/392 reads (8%) | called by muse, mutect2
- PCDHB1 | c.1626G>A p.L542= | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as COSV100128165; called by muse, mutect2
- PSG11 | c.615T>C p.F205= | Silent (SNP) | VAF 23/335 reads (7%) | called by muse, mutect2
- PSTK | c.942T>C p.A314= | Silent (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- SCN1A | c.663C>G p.L221= | Silent (SNP) | VAF 17/219 reads (8%) | catalogued as COSV100319219; called by muse, mutect2
- USP9X | c.7035G>A p.L2345= | Silent (SNP) | VAF 27/312 reads (9%) | called by muse, mutect2
- VN1R4 | c.420G>A p.L140= | Silent (SNP) | VAF 14/356 reads (4%) | called by muse, mutect2
- VRK1 | c.315G>A p.L105= | Silent (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- WIZ | c.1437C>G p.L479= | Silent (SNP) | VAF 38/487 reads (8%) | called by muse, mutect2
- XPO7 | c.1746G>A p.L582= | Silent (SNP) | VAF 20/253 reads (8%) | called by muse, mutect2
- ZAN | c.4827C>T p.L1609= | Silent (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- ZNF518A | c.351C>G p.L117= | Silent (SNP) | VAF 9/293 reads (3%) | called by muse, mutect2
- CHD2 | c.62+47G>A | Intron (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
- DHRS12 | c.706+520G>A | Intron (SNP) | VAF 32/481 reads (7%) | catalogued as rs1327820994; called by muse, mutect2
- IGKV1OR2-108 | chr2:113406872 ins CC | 3'Flank (INS) | VAF 28/70 reads (40%) | called by pindel, varscan2
- KCNQ1 | c.1394-16908A>G | Intron (SNP) | VAF 105/277 reads (38%) | catalogued as rs977018995; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-7073G>A | Intron (SNP) | VAF 134/302 reads (44%) | called by muse, mutect2, varscan2
- PTPRU | chr1:29325811 C>G | 3'Flank (SNP) | VAF 46/465 reads (10%) | called by muse, mutect2
- SMIM29 | c.*41G>C | 3'UTR (SNP) | VAF 53/543 reads (10%) | called by muse, mutect2
